Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6X3, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6X3-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: M

Age:

Date of surgery:

Localization: R parietal

Diagnosis: Oligoastrocytoma (grade II WHO)

Name of Pathologist:

ICD-O-3
Oligoastrocytoma 9382/3
Site Brain, supratentorial NOS-C71.0
7/8/12/13

ICD-O-3 Discrepancy		☒
Initial/Synchronous Primary Noted		☒

Source: NCI Genomic Data Commons file 414a791e-73c7-4004-a9b6-1c3cf7678af1 (TCGA-QH-A6X3.4012F789-F8D1-43DE-9570-22BC8AE1D842.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).